Somatic mutation profile of tumor specimen TCGA-RC-A6M5-01A (aliquot TCGA-RC-A6M5-01A-11D-A32G-10) from TCGA case TCGA-RC-A6M5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, fibrolamellar; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 20.9 years (7,634 days).
Specimen TCGA-RC-A6M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ee297e2-4fe7-475f-9b95-5eae176c616f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A6M5-10A (Blood Derived Normal), aliquot TCGA-RC-A6M5-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c64ec48d-b641-4d33-b801-8adf7a32253c

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBLL1 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV99755902; called by muse, mutect2, varscan2
- CDAN1 | c.2570A>G p.N857S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100661429; called by muse, mutect2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by mutect2, varscan2
- FAM155A | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.019); catalogued as COSV101030079; called by muse, mutect2, varscan2
- FNDC1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769438661, COSV51938501; called by muse, mutect2, varscan2
- FSTL1 | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV99820962; called by muse, mutect2
- LONRF1 | c.815T>G p.L272R | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV101238258; called by muse, mutect2, varscan2
- LRRK1 | c.5975G>A p.R1992K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV99442865; called by muse, mutect2
- MYOM2 | c.755A>T p.D252V | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.337); catalogued as COSV100038284; called by muse, mutect2, varscan2
- NUP50 | c.1397A>G p.K466R | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100754405; called by muse, mutect2
- SALL1 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs200755920, COSV99172001; called by muse, mutect2
- SGCZ | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as COSV101171507; called by muse, mutect2
- USP34 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV68401388; called by muse, mutect2, varscan2
- ZFR2 | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868113469, COSV99507830; called by muse, mutect2, varscan2
- ZNF700 | c.1111T>C p.F371L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99583779; called by muse, mutect2, varscan2
- CCDC8 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MKI67 | c.6837del p.M2279Ifs*35 | Frame Shift Del (DEL) | VAF 23/198 reads (12%) | called by mutect2, pindel, varscan2
- ABCA7 | c.5385G>T p.L1795= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- ADH4 | c.804G>C p.V268= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99644382; called by muse, mutect2
- MYH11 | c.4510C>A p.R1504= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as COSV100260119; called by muse, mutect2, varscan2
- NFE2L3 | c.1284T>C p.N428= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs769682486, COSV50226423; called by mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 4/31 reads (13%) | catalogued as rs201441562; called by pindel, varscan2
